Somatic mutation profile of cancer-model specimen HCM-CSHL-0907-C50-85B (3D Organoid, passage 8; aliquot HCM-CSHL-0907-C50-85B-01D-A882-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0907-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 74.6 years (27,246 days).
Specimen HCM-CSHL-0907-C50-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 451eb785-e9ec-4e9f-a6ba-b023b182319c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0907-C50-10A (Blood Derived Normal), aliquot HCM-CSHL-0907-C50-10A-01D-A882-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/170b2695-1f2c-4972-818c-80ab965fe649

The open-access MAF lists 185 somatic variants for this specimen: 134 protein-altering or splice-affecting, 42 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 108, Silent 42, Nonsense Mutation 11, Frame Shift Del 7, Frame Shift Ins 3, 3'Flank 3, 5'UTR 2, Intron 2, In Frame Del 2, 3'UTR 1, Splice Region 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 264/264 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCD2 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 97/811 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764791765; called by muse, mutect2, varscan2
- AKNA | c.2680G>A p.G894S | Missense Mutation (SNP) | VAF 101/216 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.685); catalogued as rs760033051; called by muse, mutect2, varscan2
- ANKRD13B | c.1410G>A p.T470= | Splice Region (SNP) | VAF 85/273 reads (31%) | catalogued as rs778298359; called by muse, mutect2, varscan2
- ANKRD6 | c.1409C>G p.S470C | Missense Mutation (SNP) | VAF 49/244 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369677070; called by muse, mutect2, varscan2
- ASXL2 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 130/256 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs770538687, COSV55452840, COSV99711309; called by muse, mutect2, varscan2
- ATP11C | c.3281G>A p.R1094K | Missense Mutation (SNP) | VAF 45/294 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100557680; called by muse, mutect2, varscan2
- AUTS2 | c.1792G>A p.G598S | Missense Mutation (SNP) | VAF 107/575 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1183738885, COSV61393013, COSV61399130; called by muse, mutect2, varscan2
- CAMSAP3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 50/219 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1478449306; called by muse, mutect2, varscan2
- CD300A | c.217G>A p.G73S | Missense Mutation (SNP) | VAF 223/347 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as rs371212903; called by muse, mutect2, varscan2
- CDH26 | c.682C>T p.R228* | Nonsense Mutation (SNP) | VAF 74/377 reads (20%) | catalogued as rs766848205, COSV54844761; called by muse, mutect2, varscan2
- CLK3 | c.1708C>T p.R570W (on ENST00000395066 / NM_001130028.1; = p.R422W on NM_003992.4) | Missense Mutation (SNP) | VAF 74/229 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs528836636; called by muse, mutect2, varscan2
- CROCC | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 110/692 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); catalogued as COSV65011578; called by muse, varscan2
- CSMD3 | c.2728G>C p.G910R (on ENST00000297405 / NM_001363185.1; = p.G806R on NM_052900.3) | Missense Mutation (SNP) | VAF 83/604 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52124933; called by muse, mutect2, varscan2
- EIF3B | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 156/156 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as rs551734577; called by muse, mutect2, varscan2
- ERCC3 | c.25C>A p.R9S | Missense Mutation (SNP) | VAF 410/659 reads (62%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.931); catalogued as rs1319949323; called by muse, mutect2, varscan2
- FAM47B | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 383/633 reads (61%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as rs368902203, COSV61452510, COSV61454357; called by muse, mutect2, varscan2
- FANCA | c.3193G>A p.V1065M | Missense Mutation (SNP) | VAF 88/527 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs140124051; called by muse, mutect2, varscan2
- FBXO41 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 87/517 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1421892734; called by muse, mutect2, varscan2
- FCRL5 | c.2476G>A p.G826R | Missense Mutation (SNP) | VAF 76/392 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV62511447; called by muse, mutect2, varscan2
- FLG | c.2365C>G p.R789G | Missense Mutation (SNP) | VAF 80/1919 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV64247792; called by muse, mutect2
- H4C4 | c.79A>G p.I27V | Missense Mutation (SNP) | VAF 105/489 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.765); catalogued as rs780528340; called by muse, mutect2, varscan2
- HGH1 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 267/1743 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs1200176463; called by muse, mutect2, varscan2
- HSPG2 | c.5304C>G p.S1768R | Missense Mutation (SNP) | VAF 76/234 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.358); catalogued as COSV65969025; called by muse, mutect2, varscan2
- IGHMBP2 | c.2398G>A p.G800S | Missense Mutation (SNP) | VAF 150/845 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751122806, COSV104369681; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGLV2-8 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 240/512 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.529); catalogued as rs1467923252; called by muse, mutect2, varscan2
- LILRB2 | c.1021G>T p.V341L | Missense Mutation (SNP) | VAF 102/650 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV100078905; called by muse, mutect2
- MAPK15 | c.1058C>T p.S353L | Missense Mutation (SNP) | VAF 143/1249 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs201591856; called by muse, mutect2, varscan2
- MC3R | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 260/694 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371599272; called by muse, mutect2, varscan2
- MCM2 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 75/341 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs778548957; called by muse, mutect2, varscan2
- MUC16 | c.7190C>G p.S2397* | Nonsense Mutation (SNP) | VAF 63/320 reads (20%) | catalogued as COSV67476394; called by muse, mutect2, varscan2
- NFATC4 | c.1739G>A p.R580H | Missense Mutation (SNP) | VAF 96/253 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs374847716; called by muse, mutect2, varscan2
- NRSN2 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 285/285 reads (100%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs372791832; called by muse, varscan2
- NRSN2 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 308/308 reads (100%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs905109408, COSV66526790; called by muse, mutect2, varscan2
- NUDT3 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 43/225 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV101657173; called by muse, mutect2, varscan2
- OAF | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 93/415 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749392944, COSV61109591; called by muse, mutect2, varscan2
- OBSL1 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 152/379 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.183); catalogued as rs990876533; called by muse, mutect2, varscan2
- OCSTAMP | c.1120G>A p.V374I | Missense Mutation (SNP) | VAF 240/641 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV54096479; called by muse, mutect2, varscan2
- OSCAR | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 211/841 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs1363268951; called by muse, mutect2, varscan2
- PURG | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 84/173 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.571); catalogued as rs774060872, COSV53300443; called by muse, mutect2, varscan2
- PXDN | c.2635G>A p.V879M | Missense Mutation (SNP) | VAF 218/433 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs765506698; called by muse, mutect2, varscan2
- QKI | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 31/398 reads (8%) | catalogued as COSV51688694; called by muse, mutect2
- RABGAP1L | c.705G>C p.L235F (on ENST00000489615 / NM_001243765.2; = p.L118F on NM_001243764.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/327 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57722445; called by muse, mutect2, varscan2
- RBM10 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 142/1059 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.471); catalogued as COSV61308444; called by muse, varscan2
- RGS20 | c.682G>T p.D228Y (on ENST00000297313 / NM_170587.4; = p.D81Y on NM_003702.4) | Missense Mutation (SNP) | VAF 61/388 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV52013811; called by muse, mutect2, varscan2
- RNF126 | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 133/554 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1457055494; called by muse, mutect2, varscan2
- SLC22A14 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 86/302 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs375724554; called by muse, mutect2, varscan2
- SMARCA4 | c.2059A>G p.K687E | Missense Mutation (SNP) | VAF 161/328 reads (49%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs751565055, COSV60802258; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- THOC5 | c.1646A>G p.N549S | Missense Mutation (SNP) | VAF 93/444 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs762452125; called by muse, mutect2
- TMEM132D | c.1269G>T p.K423N | Missense Mutation (SNP) | VAF 14/357 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV101395893; called by muse, mutect2
- TSPYL4 | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 106/410 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1379050886; called by muse, mutect2, varscan2
- TTN | c.97822G>C p.D32608H (on ENST00000591111; = p.D25184H on NM_003319.4) | Missense Mutation (SNP) | VAF 107/371 reads (29%) | PolyPhen probably damaging (0.999); catalogued as COSV59966119; called by muse, mutect2, varscan2
- UTP25 | c.1357dup p.L453Pfs*18 | Frame Shift Ins (INS) | VAF 91/470 reads (19%) | catalogued as rs769364542; called by mutect2, pindel, varscan2
- WARS2 | c.1027A>G p.K343E | Missense Mutation (SNP) | VAF 107/445 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs916656828; called by muse, mutect2, varscan2
- WNT7B | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 166/735 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1372602740; called by muse, mutect2, varscan2
- WWP2 | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 73/221 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs746677032; called by muse, mutect2, varscan2
- ZNF496 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 100/467 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as rs367771669; called by muse, mutect2, varscan2
- AARS2 | c.1687A>G p.N563D | Missense Mutation (SNP) | VAF 264/591 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- AC244197.3 | c.1014G>A p.M338I | Missense Mutation (SNP) | VAF 41/304 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKAP10 | c.1072G>C p.E358Q | Missense Mutation (SNP) | VAF 71/211 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ANKRD12 | c.3691T>A p.S1231T | Missense Mutation (SNP) | VAF 150/412 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); called by mutect2, varscan2
- ARMC8 | c.1096G>A p.A366T (on ENST00000469044 / NM_001363941.2; = p.A352T on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 282/282 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- ARMCX5 | c.1055del p.G352Vfs*5 | Frame Shift Del (DEL) | VAF 154/494 reads (31%) | called by mutect2, pindel, varscan2
- BEST4 | c.1259C>T p.A420V | Missense Mutation (SNP) | VAF 171/544 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BRSK1 | c.498G>C p.E166D | Missense Mutation (SNP) | VAF 60/271 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- C1orf112 | c.1741G>A p.A581T | Missense Mutation (SNP) | VAF 238/238 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- CASC3 | c.1142C>G p.S381* | Nonsense Mutation (SNP) | VAF 79/324 reads (24%) | called by muse, mutect2, varscan2
- CBARP | c.635C>A p.A212D (on ENST00000382477; = p.A192D on NM_152769.3) | Missense Mutation (SNP) | VAF 343/742 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- CFAP47 | c.7038G>A p.W2346* | Nonsense Mutation (SNP) | VAF 51/317 reads (16%) | called by muse, mutect2, varscan2
- CNBD1 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 73/339 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- COL22A1 | c.4022C>A p.S1341* | Nonsense Mutation (SNP) | VAF 92/860 reads (11%) | called by muse, mutect2, varscan2
- CPD | c.180C>A p.H60Q | Missense Mutation (SNP) | VAF 171/564 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- CPED1 | c.1484C>T p.P495L | Missense Mutation (SNP) | VAF 64/342 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CSTF3 | c.2012A>G p.N671S | Missense Mutation (SNP) | VAF 190/190 reads (100%) | SIFT tolerated (0.81); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CTNND1 | c.2548C>T p.Q850* (on ENST00000399050 / NM_001085458.2; = p.Q844* on NM_001331.3) | Nonsense Mutation (SNP) | VAF 49/215 reads (23%) | called by muse, mutect2, varscan2
- CYP11B1 | c.1351C>T p.L451F | Missense Mutation (SNP) | VAF 187/1315 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CYP11B2 | c.127C>A p.Q43K | Missense Mutation (SNP) | VAF 254/1183 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- DIPK1B | c.1032dup p.D345Rfs*7 | Frame Shift Ins (INS) | VAF 157/380 reads (41%) | called by mutect2, pindel, varscan2
- DNAH10 | c.3335T>C p.L1112P (on ENST00000409039; = p.L1051P on NM_207437.3) | Missense Mutation (SNP) | VAF 75/319 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- DPEP1 | c.229G>C p.G77R | Missense Mutation (SNP) | VAF 346/611 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- EIF3E | c.413A>G p.Q138R | Missense Mutation (SNP) | VAF 36/535 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.12); called by muse, mutect2
- FAM171A2 | c.1781del p.G594Afs*44 | Frame Shift Del (DEL) | VAF 120/474 reads (25%) | called by pindel, varscan2
- FASTKD2 | c.581G>T p.R194I | Missense Mutation (SNP) | VAF 248/343 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- FGD1 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 148/1158 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.081); called by mutect2, varscan2
- FHDC1 | c.3347G>A p.R1116K | Missense Mutation (SNP) | VAF 101/639 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FMNL2 | c.2490C>A p.N830K | Missense Mutation (SNP) | VAF 51/294 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- GRIPAP1 | c.517G>A p.G173R | Missense Mutation (SNP) | VAF 157/1069 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HIP1 | c.361T>G p.L121V | Missense Mutation (SNP) | VAF 139/648 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- HSPA8 | c.1441G>A p.D481N | Missense Mutation (SNP) | VAF 79/471 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- KCNB2 | c.2732T>A p.M911K | Missense Mutation (SNP) | VAF 52/392 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- KCNU1 | c.844G>T p.V282L | Missense Mutation (SNP) | VAF 95/277 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- KRT16 | c.1422G>C p.*474Yext*2 | Nonstop Mutation (SNP) | VAF 58/226 reads (26%) | called by muse, mutect2, varscan2
- KRTAP1-1 | c.282_293del p.C95_G98del | In Frame Del (DEL) | VAF 107/551 reads (19%) | called by mutect2, pindel, varscan2
- LAMB1 | c.1742C>G p.P581R | Missense Mutation (SNP) | VAF 271/1107 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MAP3K3 | c.1167_1169del p.S390del | In Frame Del (DEL) | VAF 232/237 reads (98%) | called by mutect2, pindel, varscan2
- MAP7D2 | c.1972A>G p.I658V | Missense Mutation (SNP) | VAF 37/241 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- MGA | c.3310G>A p.A1104T | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- MOSPD2 | c.372C>G p.D124E | Missense Mutation (SNP) | VAF 77/500 reads (15%) | SIFT tolerated (0.98); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- MTIF3 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 91/184 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- MUC5AC | c.1549C>A p.Q517K | Missense Mutation (SNP) | VAF 13/207 reads (6%) | SIFT deleterious (0.03); called by muse, mutect2
- MYO15A | c.1635_1636del p.L546Vfs*14 | Frame Shift Del (DEL) | VAF 161/659 reads (24%) | called by pindel, varscan2
- NEXMIF | c.2137G>C p.E713Q | Missense Mutation (SNP) | VAF 121/608 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- NHP2 | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 71/276 reads (26%) | called by muse, mutect2, varscan2
- NSD1 | c.4135C>T p.P1379S | Missense Mutation (SNP) | VAF 18/365 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2
- OR2T34 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 53/363 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PDF | c.63_67dup p.A23Gfs*32 | Frame Shift Ins (INS) | VAF 298/518 reads (58%) | called by mutect2, varscan2
- PEPD | c.1260C>A p.H420Q | Missense Mutation (SNP) | VAF 192/851 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- PLCB3 | c.3631G>T p.G1211C | Missense Mutation (SNP) | VAF 189/976 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- POTEE | c.1626G>C p.M542I | Missense Mutation (SNP) | VAF 68/878 reads (8%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.01); called by muse, mutect2
- PPIAL4G | c.151T>A p.S51T | Missense Mutation (SNP) | VAF 441/3886 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.673); called by mutect2, varscan2
- PRDM5 | c.214G>C p.D72H | Missense Mutation (SNP) | VAF 142/230 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PUF60 | c.582G>A p.M194I (on ENST00000526683 / NM_001362896.2; = p.M177I on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 279/1299 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PURG | c.281G>A p.R94K | Missense Mutation (SNP) | VAF 115/237 reads (49%) | SIFT tolerated (1); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- RBMXL3 | c.3102del p.L1036Cfs*62 | Frame Shift Del (DEL) | VAF 174/290 reads (60%) | called by pindel, varscan2
- RGP1 | c.551A>G p.E184G | Missense Mutation (SNP) | VAF 94/549 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- RNF141 | c.595A>G p.N199D | Missense Mutation (SNP) | VAF 218/219 reads (100%) | SIFT tolerated (0.72); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RYR1 | c.1606_1622del p.C536Kfs*28 | Frame Shift Del (DEL) | VAF 36/342 reads (11%) | called by mutect2, pindel
- SIX4 | c.1292C>T p.A431V | Missense Mutation (SNP) | VAF 93/297 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLAMF1 | c.825A>T p.K275N | Missense Mutation (SNP) | VAF 387/481 reads (80%) | SIFT tolerated (0.4); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- SLC2A11 | c.707C>T p.S236F (on ENST00000345044 / NM_001024938.4; = p.S243F on NM_030807.5) | Missense Mutation (SNP) | VAF 276/567 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SLC3A2 | c.1843A>T p.K615* | Nonsense Mutation (SNP) | VAF 130/603 reads (22%) | called by muse, varscan2
- SNX13 | c.2346_2349del p.E782Dfs*4 | Frame Shift Del (DEL) | VAF 47/269 reads (17%) | called by mutect2, pindel, varscan2
- SRA1 | c.500_515del p.E167Gfs*17 | Frame Shift Del (DEL) | VAF 120/211 reads (57%) | called by mutect2, pindel, varscan2
- SS18L2 | c.5C>G p.S2W | Missense Mutation (SNP) | VAF 99/314 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TNMD | c.508A>T p.K170* | Nonsense Mutation (SNP) | VAF 106/608 reads (17%) | called by muse, mutect2, varscan2
- TNXB | c.12920G>C p.C4307S (on ENST00000647633; = p.C4060S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 181/832 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TOGARAM1 | c.3694G>A p.E1232K | Missense Mutation (SNP) | VAF 65/240 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TTC3 | c.1870G>C p.E624Q | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UGT2B4 | c.137T>G p.L46R | Missense Mutation (SNP) | VAF 83/228 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USH2A | c.8351T>C p.I2784T | Missense Mutation (SNP) | VAF 32/390 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.045); called by muse, mutect2
- ZBTB44 | c.1128C>A p.Y376* | Nonsense Mutation (SNP) | VAF 63/393 reads (16%) | called by mutect2, varscan2
- ZNF235 | c.1336C>T p.L446F | Missense Mutation (SNP) | VAF 83/355 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- ZNF382 | c.1370T>A p.I457N | Missense Mutation (SNP) | VAF 191/278 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZNF814 | c.1799G>C p.G600A | Missense Mutation (SNP) | VAF 98/474 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- A1BG | c.993C>T p.G331= | Silent (SNP) | VAF 153/713 reads (21%) | catalogued as rs1209596790; called by muse, mutect2, varscan2
- A1CF | c.1173G>A p.A391= (on ENST00000373993 / NM_138932.2; = p.A383= on NM_014576.4) | Silent (SNP) | VAF 70/189 reads (37%) | catalogued as rs754054312, COSV50957004; called by muse, mutect2, varscan2
- ACACB | c.5064C>T p.H1688= | Silent (SNP) | VAF 179/376 reads (48%) | catalogued as rs764448953, COSV58142107; called by muse, mutect2, varscan2
- ACIN1 | c.3261C>G p.A1087= | Silent (SNP) | VAF 65/189 reads (34%) | called by muse, mutect2, varscan2
- APH1A | c.797G>A p.*266= | Silent (SNP) | VAF 98/2704 reads (4%) | called by muse, mutect2
- ARHGAP10 | c.2091C>T p.S697= | Silent (SNP) | VAF 256/700 reads (37%) | called by muse, mutect2, varscan2
- ATPAF1 | c.420G>A p.K140= (on ENST00000574428; = p.K163= on NM_022745.4) | Silent (SNP) | VAF 54/195 reads (28%) | catalogued as rs779542690; called by muse, mutect2, varscan2
- BOP1 | c.762G>A p.E254= | Silent (SNP) | VAF 132/1299 reads (10%) | called by muse, mutect2, varscan2
- CAPN13 | c.1293A>G p.R431= | Silent (SNP) | VAF 88/415 reads (21%) | called by muse, mutect2, varscan2
- CCDC7 | c.234A>C p.L78= | Silent (SNP) | VAF 54/479 reads (11%) | called by muse, mutect2, varscan2
- CPSF1 | c.471G>A p.T157= | Silent (SNP) | VAF 152/1332 reads (11%) | catalogued as rs782110470; called by muse, mutect2, varscan2
- DLL3 | c.357C>T p.T119= | Silent (SNP) | VAF 46/261 reads (18%) | called by muse, mutect2, varscan2
- DNAH6 | c.7188G>A p.E2396= | Silent (SNP) | VAF 70/347 reads (20%) | catalogued as COSV52849318; called by muse, mutect2, varscan2
- DNAH9 | c.2883T>C p.S961= | Silent (SNP) | VAF 88/329 reads (27%) | called by muse, mutect2, varscan2
- FAM161B | c.723G>A p.T241= (on ENST00000651776; = p.T178= on NM_152445.3) | Silent (SNP) | VAF 291/433 reads (67%) | catalogued as rs754031440; called by muse, mutect2, varscan2
- FAM171A2 | c.1941G>T p.V647= | Silent (SNP) | VAF 146/482 reads (30%) | called by muse, varscan2
- FGD1 | c.2301C>T p.F767= | Silent (SNP) | VAF 99/1074 reads (9%) | called by muse, mutect2
- FOXN1 | c.1521C>T p.A507= | Silent (SNP) | VAF 185/568 reads (33%) | catalogued as rs146492596; called by muse, mutect2, varscan2
- GALNS | c.834G>A p.A278= | Silent (SNP) | VAF 232/505 reads (46%) | catalogued as rs148759644; called by muse, mutect2, varscan2
- GREB1 | c.1788A>G p.V596= | Silent (SNP) | VAF 80/306 reads (26%) | called by muse, mutect2, varscan2
- KBTBD6 | c.1560C>T p.V520= | Silent (SNP) | VAF 109/215 reads (51%) | called by muse, mutect2, varscan2
- KBTBD7 | c.150G>T p.L50= | Silent (SNP) | VAF 287/287 reads (100%) | called by muse, mutect2, varscan2
- KCNA5 | c.591G>A p.A197= | Silent (SNP) | VAF 394/1245 reads (32%) | catalogued as rs1443012925; called by muse, mutect2, varscan2
- KCNN3 | c.2079C>T p.A693= (on ENST00000618040 / NM_001204087.1; = p.A678= on NM_002249.6) | Silent (SNP) | VAF 558/704 reads (79%) | catalogued as rs747394806, COSV99679556; called by muse, mutect2, varscan2
- KCNV1 | c.951C>T p.L317= | Silent (SNP) | VAF 92/825 reads (11%) | called by muse, mutect2, varscan2
- KDM4C | c.1641C>A p.V547= | Silent (SNP) | VAF 74/565 reads (13%) | called by muse, mutect2, varscan2
- KLHL7 | c.162G>A p.K54= (on ENST00000339077 / NM_001031710.3; = p.K6= on NM_018846.5) | Silent (SNP) | VAF 146/304 reads (48%) | called by muse, mutect2, varscan2
- LIM2 | c.51C>T p.I17= | Silent (SNP) | VAF 164/554 reads (30%) | called by muse, mutect2, varscan2
- MISP3 | c.921G>A p.E307= (on ENST00000269720; = p.E165= on NM_001291291.2) | Silent (SNP) | VAF 272/548 reads (50%) | called by muse, mutect2, varscan2
- OBSL1 | c.9G>A p.A3= | Silent (SNP) | VAF 80/211 reads (38%) | called by muse, varscan2
- PHF8 | c.2592G>A p.L864= (on ENST00000357988 / NM_001184896.1; = p.L828= on NM_015107.3) | Silent (SNP) | VAF 74/784 reads (9%) | called by muse, mutect2
- PREX2 | c.3436T>C p.L1146= | Silent (SNP) | VAF 63/375 reads (17%) | called by muse, mutect2, varscan2
- SLC26A1 | c.2049C>T p.A683= | Silent (SNP) | VAF 109/1279 reads (9%) | catalogued as rs145384499; called by muse, mutect2
- SLC39A4 | c.1245G>T p.L415= (on ENST00000301305 / NM_001374839.1; = p.L390= on NM_017767.3) | Silent (SNP) | VAF 120/1094 reads (11%) | called by mutect2, varscan2
- TEDC1 | c.177T>A p.R59= | Silent (SNP) | VAF 168/504 reads (33%) | called by muse, mutect2, varscan2
- TFE3 | c.99C>T p.D33= | Silent (SNP) | VAF 413/902 reads (46%) | called by muse, mutect2, varscan2
- TMEM200B | c.432G>A p.T144= | Silent (SNP) | VAF 149/543 reads (27%) | called by muse, mutect2, varscan2
- TNS1 | c.2973G>A p.A991= | Silent (SNP) | VAF 94/176 reads (53%) | catalogued as rs376403287; called by muse, varscan2
- TTC21A | c.1287G>C p.L429= | Silent (SNP) | VAF 106/338 reads (31%) | called by muse, mutect2, varscan2
- XPO6 | c.1851C>A p.L617= | Silent (SNP) | VAF 57/230 reads (25%) | called by muse, mutect2, varscan2
- ZNF487 | c.222G>C p.L74= | Silent (SNP) | VAF 79/274 reads (29%) | called by muse, mutect2, varscan2
- ZNF587 | c.66G>T p.V22= | Silent (SNP) | VAF 42/256 reads (16%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73820842 C>G | 3'Flank (SNP) | VAF 82/452 reads (18%) | called by muse, mutect2, varscan2
- ATG16L1 | c.-62dup | 5'UTR (INS) | VAF 119/356 reads (33%) | called by mutect2, pindel, varscan2
- CFAP92 | chr3:128965597 G>C | 3'Flank (SNP) | VAF 93/320 reads (29%) | called by muse, mutect2, varscan2
- HAGHL | c.*139T>G | 3'UTR (SNP) | VAF 125/709 reads (18%) | called by muse, mutect2, varscan2
- KMT2E | c.1722+90C>G | Intron (SNP) | VAF 163/553 reads (29%) | catalogued as rs1554397399; called by muse, mutect2, varscan2
- MYADM | chr19:53874148 G>C | 3'Flank (SNP) | VAF 139/636 reads (22%) | catalogued as COSV61239354; called by muse, mutect2, varscan2
- NLRP7 | c.2810+2809C>G | Intron (SNP) | VAF 146/640 reads (23%) | called by muse, mutect2, varscan2
- PURG | c.-363G>C | 5'UTR (SNP) | VAF 108/249 reads (43%) | called by muse, mutect2, varscan2
- Z99774.2 | chr22:26670490 C>G | 5'Flank (SNP) | VAF 131/250 reads (52%) | called by muse, mutect2, varscan2
